Gene-level copy-number profile of tumor specimen TCGA-HC-8265-01B from TCGA case TCGA-HC-8265, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-HC-8265-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ae7f9566-e03e-4edd-8dbe-ceae61b47d10.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-8265-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/41299d2a-68e6-475e-9820-c9d2809e8d54

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,436; copy number 2: 56,897; copy number 3: 842; copy number 4: 64; copy number 5: 18; copy number 6: 5; copy number 7: 8; copy number 13: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-8265-01A-11D-2259-01): tumor purity 0.5, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,004,404–8,026,309, 1 gene, copy number 13 (within-gene range 2–13): ERRFI1.
- chr1:229,256,892–229,305,894, 2 genes, copy number 5 (within-gene range 2–5): AL162595.1, RAB4A.
- chr5:24,786,842–24,787,024, 1 gene, copy number 6: BTG4P1.
- chr6:5,997,999–6,007,605, 1 gene, copy number 7: NRN1.
- chr6:33,437,363–33,454,453, 1 gene, copy number 5 (within-gene range 2–5): SYNGAP1-AS1.
- chr6:33,453,970–33,457,544, 1 gene, copy number 5: ZBTB9.
- chr9:95,506,235–95,507,636, 1 gene, copy number 7: AL161729.1.
- chr12:14,762,504–14,803,486, 4 genes, copy number 5: AC010168.2, H4-16, H2AJ, WBP11.
- chr12:14,805,108–14,808,177, 1 gene, copy number 5: AC007655.2.
- chr14:37,171,888–37,596,059, 7 genes, copy number 5: SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr15:25,333,728–25,439,051, 2 genes, copy number 5: UBE3A, AC100774.1.
- chr15:85,579,046–85,580,178, 1 gene, copy number 7: AC087286.3.
- chr15:85,621,264–85,627,689, 1 gene, copy number 7: AC087286.1.
- chr16:1,911,475–1,961,975, 4 genes, copy number 6 (within-gene range 2–6): HS3ST6, MSRB1, RPL3L, NDUFB10.
- chr22:22,086,561–22,104,857, 4 genes, copy number 7: IGLV1-62, AC245517.5, IGLV8-61, AC245517.1.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
